Somatic mutation profile of tumor specimen TCGA-TQ-A7RG-01A (aliquot TCGA-TQ-A7RG-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RG, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 36.2 years (13,227 days).
Specimen TCGA-TQ-A7RG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e863178-ebf2-492b-a025-afc97cc1515b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RG-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RG-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f23269cc-1ce9-474f-8b05-6365f76fcef0

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 15, Silent 8, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.452+2dup p.X151_splice | Splice Site (INS) | VAF 5/41 reads (12%) | hotspot (GDC flag); called by mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 79/204 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BMP6 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs566660170, COSV51660551; called by muse, mutect2
- CHD6 | c.5648G>C p.G1883A | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.009); catalogued as COSV100951393; called by muse, mutect2, varscan2
- CPNE3 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as rs1386387971, COSV99548160; called by muse, mutect2, varscan2
- DPPA5 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV64876106; called by muse, mutect2, varscan2
- FGD5 | c.3301G>A p.V1101I | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs199676271; called by muse, mutect2, varscan2
- GJA8 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs782051936, COSV53789781, COSV53791306; called by muse, mutect2
- KLHDC7B | c.1504C>T p.R502W (on ENST00000395676; = p.R1143W on NM_138433.5) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758075611, COSV67464366; called by muse, mutect2
- MDGA2 | c.2916A>G p.I972M (on ENST00000399232 / NM_001113498.2; = p.I674M on NM_182830.4) | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV100638631; called by muse, mutect2, varscan2
- MFHAS1 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.761); catalogued as rs1187160545, COSV99359993; called by muse, mutect2
- NIPBL | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 21/205 reads (10%) | catalogued as COSV99242925; called by muse, mutect2
- OR4P4 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV58923744; called by muse, mutect2
- POGLUT3 | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.674); catalogued as COSV100052821; called by muse, mutect2, varscan2
- PROKR1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 27/339 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs771784209, COSV58137160; called by muse, mutect2
- STAB1 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as COSV100402340; called by muse, mutect2, varscan2
- TBC1D10A | c.1087C>G p.R363G | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV53163321, COSV99304998; called by muse, mutect2, varscan2
- TSHZ3 | c.1572A>T p.K524N | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV99552941; called by muse, mutect2, varscan2
- TULP4 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as rs749219648, COSV100893880; called by muse, mutect2, varscan2
- KAZN | c.750dup p.T251Dfs*122 | Frame Shift Ins (INS) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- ZBTB18 | c.35dup p.C13Vfs*13 | Frame Shift Ins (INS) | VAF 33/116 reads (28%) | called by mutect2, pindel, varscan2
- ALS2 | c.381C>T p.N127= | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as COSV99970139; called by muse, mutect2, varscan2
- GABBR2 | c.2061C>T p.N687= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs1286722453, COSV99411788; called by muse, mutect2
- KHNYN | c.1092G>A p.P364= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs986849793, COSV52160259; called by muse, mutect2, varscan2
- MICB | c.552G>A p.Q184= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV99357602; called by muse, mutect2, varscan2
- MRPS31 | c.1014G>A p.L338= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as rs1408221627, COSV100062542; called by muse, mutect2, varscan2
- NHLRC2 | c.834T>C p.F278= | Silent (SNP) | VAF 15/246 reads (6%) | catalogued as COSV100993036; called by muse, mutect2
- NLRC5 | c.4809G>A p.R1603= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV52661222, COSV99348382; called by muse, mutect2, varscan2
- PCDHA1 | c.1119C>T p.T373= | Silent (SNP) | VAF 34/198 reads (17%) | catalogued as rs782808595, COSV100974534, COSV65373460; called by muse, mutect2, varscan2
